Gene-level copy-number profile of tumor specimen TCGA-18-3414-01A from TCGA case TCGA-18-3414, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 73.8 years (26,938 days).
Specimen TCGA-18-3414-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.05a9bbb7-bfec-4741-bf08-2166086b217f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-18-3414-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/331e37ea-931b-46f0-8ef4-51f8cb82f402

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 50; copy number 1: 9,245; copy number 2: 33,804; copy number 3: 14,824; copy number 4: 681; copy number 5: 146; copy number 6: 257; copy number 7: 724; copy number 8: 11; copy number 9: 29; copy number 10: 24; copy number 12: 1; copy number 15: 2; copy number 16: 4; copy number 17: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-18-3414-01A-01D-0978-01): tumor purity 0.77, ploidy 2.21, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 42 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–26,118,408, 40 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, AL353730.1, TUSC1, LINC01241, FAM71BP1, AL353753.1.
- chr18:76,974,690–76,984,162, 1 gene: AC093330.1.
- chr18:77,002,849–77,006,846, 1 gene: AC093330.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,207 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:47,905,678–52,702,615, 48 genes, copy number 6–8: AC079807.1, AC092650.1, PPIAP62, VN1R18P, RN7SKP224, FOXN2, RNU4-49P, AC093635.1, PPP1R21, RNU6-282P, STON1, STON1-GTF2A1L, GTF2A1L, AC073082.1, TPT1P11, LHCGR, ELOBP3, AC009975.1, CTBP2P5, FSHR, MIR548BA, AC009975.2, RNU6-439P, AC009971.1, RPL7P13, SNORA75, NRXN1, AC068725.1, MTCO1P42, AC009234.1, MIR8485, AC007560.1, AC007682.1, AC007402.1, AC007402.2, KNOP1P3, CRYGGP, AC097463.1, CCDC12P1, AC079304.1, ZNF863P, Y_RNA, LINC01867, GGCTP3, AC139712.1, CRTC1P1, FTH1P6, MIR4431.
- chr2:59,014,354–64,019,428, 100 genes, copy number 7–17 (broad region; genes not listed).
- chr2:80,572,681–86,213,790, 93 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 5–7 (broad region; genes not listed).
- chr9:60,914,407–72,838,297, 233 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr11:22,445,673–22,625,823, 3 genes, copy number 5: LINC01495, AC055878.1, FANCF.
- chr11:29,335,878–29,989,328, 6 genes, copy number 6 (within-gene range 4–6): LINC02755, AC090124.2, AC090124.1, AC110058.1, LINC02546, HNRNPRP2.
- chr11:29,721,399–29,726,565, 2 genes, copy number 6: RN7SL240P, RPL7AP58.
- chr11:35,662,775–36,289,449, 12 genes, copy number 5 (within-gene range 4–5): TRIM44, AC090692.2, KRT18P14, AC090692.3, AC090692.1, LDLRAD3, AL136146.1, AL136146.2, RPL12P31, MIR3973, AC129502.1, COMMD9.

Autosomal genes at a single copy (total copy number 1): 6,866. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
